Somatic mutation profile of tumor specimen TCGA-BR-6801-01A (aliquot TCGA-BR-6801-01A-11D-1882-08) from TCGA case TCGA-BR-6801, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 70.2 years (25,637 days).
Specimen TCGA-BR-6801-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47b5a9af-a0bb-493e-8d2b-41f80e7a8f7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6801-10A (Blood Derived Normal), aliquot TCGA-BR-6801-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62bd13a4-e5c9-49e4-8c45-d3df29eca9fb

The open-access MAF lists 50 somatic variants for this specimen: 33 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 16, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY2 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57899636, COSV99073547; called by muse, mutect2, varscan2
- ATP8B4 | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 177/308 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778511160, COSV52710199; called by muse, mutect2, varscan2
- BCAS1 | c.218C>A p.A73E | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs757394101, COSV65086533, COSV65089297; called by muse, mutect2, varscan2
- BCL9L | c.3380dup p.P1128Tfs*42 | Frame Shift Ins (INS) | VAF 26/52 reads (50%) | catalogued as rs751794665; called by mutect2, varscan2
- C7orf33 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV61023766; called by muse, mutect2, varscan2
- CDC5L | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs773109480, COSV65177224; called by muse, mutect2, varscan2
- CIP2A | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV55421370; called by muse, mutect2, varscan2
- DNAJA2 | c.173C>G p.S58* | Nonsense Mutation (SNP) | VAF 15/201 reads (7%) | catalogued as COSV57695532; called by muse, mutect2
- DUOX1 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 85/168 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748345295, COSV58486452; called by muse, mutect2, varscan2
- FIZ1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV55608528; called by muse, mutect2, varscan2
- IGDCC3 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.054); catalogued as COSV60080224; called by muse, mutect2
- ISLR2 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0.28); catalogued as COSV62303730; called by muse, mutect2, varscan2
- LAMA1 | c.6562C>T p.R2188C | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202184749, COSV67544266; called by muse, mutect2, varscan2
- MBD6 | c.2345dup p.A783Sfs*10 | Frame Shift Ins (INS) | VAF 36/79 reads (46%) | catalogued as rs746267361; called by mutect2, varscan2
- MSANTD1 | c.201G>C p.Q67H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV70873356; called by muse, mutect2, varscan2
- NBN | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 175/239 reads (73%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as rs1467034784, COSV55376938; called by muse, mutect2, varscan2
- NR4A2 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 73/127 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.18); catalogued as rs1331383387, COSV59895630; called by muse, mutect2, varscan2
- PELP1 | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.022); catalogued as rs558960670, COSV52585752; called by muse, mutect2, varscan2
- PTPRH | c.2849T>C p.V950A | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.281); catalogued as COSV54750123; called by muse, mutect2, varscan2
- SCN10A | c.4744C>T p.R1582C | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs569261408, COSV71861065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERINC3 | c.723C>G p.I241M | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54858522; called by muse, mutect2, varscan2
- SIPA1L1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs542018760, COSV62169330; called by muse, mutect2, varscan2
- SMG5 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 78/139 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV62437660; called by muse, mutect2, varscan2
- SPG7 | c.1402G>A p.V468I (on ENST00000268704; = p.V475I on NM_003119.4) | Missense Mutation (SNP) | VAF 70/113 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs765608610, COSV51949549; called by muse, mutect2, varscan2
- TLN1 | c.2839G>A p.G947S | Missense Mutation (SNP) | VAF 81/132 reads (61%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs570598486, COSV59211699; called by muse, mutect2, varscan2
- TRANK1 | c.8717A>T p.D2906V | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV57163835; called by muse, mutect2, varscan2
- TRIOBP | c.4380G>A p.W1460* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as rs776530766, COSV60384177; called by muse, mutect2, varscan2
- VPS13C | c.5141C>T p.S1714F (on ENST00000644861 / NM_020821.3; = p.S1671F on NM_017684.5) | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51424012; called by muse, mutect2, varscan2
- ZBTB43 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs373620611; called by muse, mutect2, varscan2
- ZNF470 | c.884A>G p.Q295R | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.768); catalogued as COSV57970682; called by muse, mutect2, varscan2
- ADH1C | c.186_189del p.P63* | Frame Shift Del (DEL) | VAF 125/245 reads (51%) | called by mutect2, pindel, varscan2
- GRID2 | c.1542del p.F514Lfs*6 | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | called by pindel, varscan2
- ZNF658 | c.2801G>A p.G934E | Missense Mutation (SNP) | VAF 140/250 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AC005324.2 | c.819G>A p.A273= | Silent (SNP) | VAF 33/56 reads (59%) | catalogued as rs551174696, COSV60885581; called by muse, mutect2, varscan2
- ADGRA2 | c.1431C>T p.V477= | Silent (SNP) | VAF 62/110 reads (56%) | catalogued as rs748619646, COSV59447200; called by muse, mutect2, varscan2
- AKAP9 | c.5691C>T p.S1897= (on ENST00000359028; = p.S1865= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV62357753; called by muse, mutect2, varscan2
- ASAP3 | c.1263G>A p.P421= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as rs1303214985, COSV60877904; called by muse, mutect2, varscan2
- C19orf57 | c.1431G>A p.P477= | Silent (SNP) | VAF 68/115 reads (59%) | catalogued as rs551002745, COSV60970293; called by muse, mutect2, varscan2
- FOXG1 | c.1272G>A p.P424= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as rs757300535, COSV57397063; called by muse, mutect2, varscan2
- HCFC1 | c.1344G>A p.L448= | Silent (SNP) | VAF 74/99 reads (75%) | catalogued as COSV60077600; called by muse, mutect2, varscan2
- HOXC11 | c.405C>T p.A135= | Silent (SNP) | VAF 159/289 reads (55%) | catalogued as COSV54533717; called by muse, mutect2, varscan2
- LANCL2 | c.1041C>G p.A347= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as COSV54652579; called by muse, mutect2, varscan2
- LRP1B | c.7218G>A p.G2406= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV67273441; called by muse, mutect2
- NEB | c.9054C>T p.D3018= | Silent (SNP) | VAF 81/146 reads (55%) | catalogued as rs756787775, COSV51459352; called by muse, mutect2, varscan2
- OBSCN | c.10542C>T p.D3514= | Silent (SNP) | VAF 80/131 reads (61%) | catalogued as rs374674963; called by muse, mutect2, varscan2
- PGR | c.687C>T p.S229= | Silent (SNP) | VAF 29/37 reads (78%) | catalogued as COSV54808904; called by muse, mutect2, varscan2
- SPTA1 | c.471C>T p.A157= | Silent (SNP) | VAF 136/213 reads (64%) | catalogued as COSV63759196; called by muse, mutect2, varscan2
- XRCC6 | c.594C>T p.I198= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV63753775; called by muse, mutect2, varscan2
- ZNF831 | c.1185C>T p.A395= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs749757214, COSV64045124; called by muse, mutect2
- AP001425.1 | chr21:38208281 T>A | 5'Flank (SNP) | VAF 129/229 reads (56%) | called by muse, mutect2, varscan2
